Gene-level copy-number profile of tumor specimen ALCH-B1T8-TTP1-A from ALCHEMIST case ALCH-B1T8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.9 years (28,466 days).
Specimen ALCH-B1T8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aa244f73-d3d7-4c1a-b9b7-7eaace135ad8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1T8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/ab3a4961-a7b0-4fc3-b4c6-7f2e743e220d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 11,692; copy number 2: 43,635; copy number 3: 2,745; copy number 4: 46; copy number 5: 201; copy number 6: 1; copy number 9: 1; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:10,280,628–10,280,891, 1 gene: RN7SL66P.
- chr2:72,916,260–72,936,071, 2 genes: EMX1, AC012366.1.
- chr2:130,129,621–130,145,134, 2 genes: MED15P9, CCDC74B.
- chr8:142,763,116–142,766,427, 1 gene (within-gene range 0–1): AC083841.1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:128,630,328–128,631,685, 1 gene (within-gene range 0–2): AL356481.3.
- chr10:5,861,616–5,889,906, 2 genes: ANKRD16, RPL12P28.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr10:49,734,641–49,762,379, 1 gene: OGDHL.
- chr12:122,920,951–122,982,913, 4 genes: ABCB9, OGFOD2, AC026362.1, ARL6IP4.
- chr12:131,896,500–131,898,239, 1 gene (within-gene range 0–2): AC131009.4.
- chr12:132,200,436–132,201,287, 1 gene (within-gene range 0–1): AC138466.4.
- chr15:25,197,576–25,211,877, 9 genes (within-gene range 0–1): SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr15:40,760,597–40,767,708, 2 genes (within-gene range 0–1): SUMO2P15, GCHFR.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–1): RNA5SP393.
- chr15:77,894,684–77,904,674, 1 gene: CSPG4P13.
- chr16:67,148,104–67,206,849, 12 genes (within-gene range 0–2): B3GNT9, TRADD, FBXL8, AC074143.1, HSF4, NOL3, KIAA0895L, EXOC3L1, E2F4, ELMO3, MIR328, AC040160.2.
- chr17:18,968,789–19,004,764, 2 genes (within-gene range 0–2): FAM83G, AC090286.4.
- chr18:79,576,460–79,589,010, 1 gene: AC068473.3.
- chr19:5,782,960–5,791,225, 3 genes: PRR22, AC011499.1, DUS3L.
- chr19:45,641,494–45,692,569, 6 genes (within-gene range 0–2): EML2-AS1, RN7SL836P, GIPR, MIR642A, MIR642B, SNRPD2.
- chr20:41,359,962–41,366,818, 1 gene (within-gene range 0–2): EMILIN3.
- chr21:44,172,169–44,194,338, 2 genes: AP001056.2, AP001056.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 204 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:795,606–981,300, 7 genes, copy number 5: ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2.
- chr5:1,173,141–11,904,446, 192 genes, copy number 5 (broad region; genes not listed).
- chr13:112,313,467–112,331,225, 2 genes, copy number 5: LINC01043, LINC01044.
- chr21:43,414,483–43,427,131, 1 gene, copy number 9: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 6 (within-gene range 4–6): LINC00313.
- chr21:44,107,373–44,131,181, 1 gene, copy number 15: PWP2.

Autosomal genes at a single copy (total copy number 1): 11,262. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
